Somatic mutation profile of tumor specimen 0DMOX4 from CCDI case PBCAFM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,122 days).
Specimen 0DMOX4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07364ec0-ed04-4843-9c27-51d7a7a48208.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMOXL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c848fd9f-b4bd-431b-8ddd-4aff829e4471

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLHL30 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 204/476 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs530687805, COSV59977639; called by muse, mutect2, varscan2
- TAS2R10 | c.587dup p.L196Ffs*104 | Frame Shift Ins (INS) | VAF 182/373 reads (49%) | catalogued as rs1406115943; called by mutect2, varscan2
- TRPV6 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 28/859 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765812934; called by muse, mutect2
- ZMYM3 | c.847del p.R283Gfs*27 | Frame Shift Del (DEL) | VAF 244/349 reads (70%) | catalogued as COSV58738115; called by mutect2, pindel, varscan2
- ZNF746 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 333/574 reads (58%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1342793238, COSV100502520; called by muse, mutect2, varscan2
- CTU2 | c.142A>G p.R48G | Missense Mutation (SNP) | VAF 175/371 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GAS1 | c.140T>G p.I47S | Missense Mutation (SNP) | VAF 51/481 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ELOA2 | c.1353G>A p.P451= | Silent (SNP) | VAF 29/364 reads (8%) | catalogued as rs1331266584, COSV55294008; called by muse, mutect2
- FAM181B | c.930G>T p.P310= | Silent (SNP) | VAF 126/276 reads (46%) | called by muse, mutect2, varscan2
- PYROXD1 | c.1068C>T p.A356= | Silent (SNP) | VAF 72/358 reads (20%) | catalogued as rs757758245; called by muse, mutect2, varscan2
- STARD13 | c.600C>T p.S200= (on ENST00000336934 / NM_001243476.3; = p.S82= on NM_052851.3) | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as rs778828160, COSV55233557; called by muse, mutect2
- CARD9 | c.1358-51T>C | Intron (SNP) | VAF 30/66 reads (45%) | catalogued as rs368858849; called by muse, mutect2, varscan2
- DEPDC7 | c.592+14G>A | Intron (SNP) | VAF 112/220 reads (51%) | called by muse, mutect2, varscan2
